Somatic mutation profile of tumor specimen TCGA-KN-8437-01A (aliquot TCGA-KN-8437-01A-11D-2310-10) from TCGA case TCGA-KN-8437, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 42.4 years (15,475 days).
Specimen TCGA-KN-8437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9312f3b0-ad86-42b9-9aee-246fa4fae28a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8437-11A (Solid Tissue Normal), aliquot TCGA-KN-8437-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdab53bd-a4ac-491d-822b-758fa4b354cf

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7280T>G p.L2427R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63869220, COSV63869886, COSV63874900; called by muse, mutect2, varscan2
- DDIT4 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV100259214; called by muse, mutect2, varscan2
- ZNF521 | c.-1G>T | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100831559; called by muse, mutect2, varscan2
- ZNF521 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALD1 | c.924C>G p.L308= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV54978374; called by muse, mutect2, varscan2
- XKR9 | c.345A>G p.E115= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV101281840; called by muse, mutect2
- ZNF668 | c.879G>C p.S293= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2047A>T | 3'UTR (SNP) | VAF 61/164 reads (37%) | called by muse, mutect2, varscan2
